Surgical pathology report (de-identified scan), TCGA case TCGA-F5-6864, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Asterand, specimen TCGA-F5-6864-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

Formatted Path Report

[REDACTED]

26 cm long colon segment. At the distance of 5 cm from one of surgical margin there is a circular, ulcerated, 9 cm long tumor; all rectum wall layers are infiltrated, with fatty tissue invasion. Fatty tissue lymph nodes are dense, grey, conglomerate-like.

Adenocarcinoma, G2, with ulceration, all wall layers infiltration, initial fatty tissue invasion, metastases in the lymph nodes conglomerate. Rectum surgical margins are free of tumor growth.

[page 2 of 3]
Tumor Features: Annular, Tumor Extent: Fat, NOS, Venous Invasion: Absent, Margins: Absent, Treatment Effect:	LARGE INTESTINE TISSUE CHECKLIST Specimen type: Resection of rectum Specimen size: Not specified Tumor site: Rectum Tumor size: 9 x 0 x 0 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Perirectal tissues Lymph nodes: 4/4 positive for metastasis (Regional 4/4) Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
---	--

Source: NCI Genomic Data Commons file c0b0a364-9f2e-4994-bc17-27a9b8617c8a (TCGA-F5-6864.6F73459C-03B5-4215-BA0A-935702977B2C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).